Somatic mutation profile of tumor specimen TCGA-WZ-A8D5-01A (aliquot TCGA-WZ-A8D5-01A-11D-A435-10) from TCGA case TCGA-WZ-A8D5, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 38.3 years (13,974 days).
Specimen TCGA-WZ-A8D5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a4028a6-727c-42a9-948b-1eb923c89297.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WZ-A8D5-10A (Blood Derived Normal), aliquot TCGA-WZ-A8D5-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a35b88f5-9e42-45a0-90b3-17ad37ab422f

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, 5'UTR 1, Splice Site 1, Frame Shift Del 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH16A1 | c.1277G>A p.G426D | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.66); catalogued as rs762446931; called by muse, mutect2, varscan2
- SUGT1 | c.538_539del p.E180Ifs*16 (on ENST00000343788 / NM_001130912.3; = p.E148Ifs*16 on NM_006704.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/139 reads (14%) | catalogued as rs778030293; called by mutect2, pindel, varscan2
- TRMT44 | c.1870A>G p.K624E | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs767729387; called by muse, mutect2, varscan2
- KRT84 | c.352G>A p.G118S | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.163); called by muse, mutect2
- ONECUT3 | c.1288A>G p.I430V | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PAIP2 | c.318+1G>A p.X106_splice | Splice Site (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- SLC35G6 | c.817G>C p.A273P | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TSPAN10 | c.781C>T p.Q261* (on ENST00000574882 / NM_001290212.1; = p.Q223* on NM_031945.4) | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- GPHB5 | c.214C>T p.L72= | Silent (SNP) | VAF 34/202 reads (17%) | catalogued as COSV100030142; called by muse, mutect2, varscan2
- GPN2 | c.81G>A p.L27= | Silent (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- SYBU | c.1323G>A p.L441= (on ENST00000276646 / NM_001099754.2; = p.L440= on NM_017786.6) | Silent (SNP) | VAF 23/146 reads (16%) | called by muse, mutect2, varscan2
- DCXR | c.*22C>A | 3'UTR (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- GOLGA4 | c.-22A>G | 5'UTR (SNP) | VAF 28/325 reads (9%) | called by muse, mutect2
